Gene-level copy-number profile of tumor specimen TCGA-24-1850-01A from TCGA case TCGA-24-1850, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 72.2 years (26,369 days).
Specimen TCGA-24-1850-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.e8c8377f-2037-4b8b-a915-cfdc8d12cfd7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1850-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 820 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e4f76ced-b1af-4138-8c62-51fbf39b6d28

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 51; copy number 1: 5,869; copy number 2: 22,577; copy number 3: 21,072; copy number 4: 5,553; copy number 5: 3,242; copy number 6: 635; copy number 7: 184; copy number 8: 96; copy number 9: 107; copy number 10: 151; copy number 11: 1; copy number 12: 15; copy number 13: 25; copy number 16: 10; copy number 20: 65; copy number 21: 34; copy number 23: 48; copy number 26: 10; copy number 27: 40; copy number 32: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1850-01A-01D-0577-01): tumor purity 0.77, ploidy 2.7, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:64,186,791–66,374,579, 32 genes (within-gene range 0–1): AL445205.1, UBE2U, RNU7-62P, CACHD1, MIR4794, RAVER2, JAK1, AL606517.2, AL606517.1, LINC01359, SLC2A3P2, AL357078.2, RNU6-1176P, MIR3671, MIR101-1, AL357078.1, MRPS21P1, AK4, RPS29P7, DNAJC6, AL139294.1, COX6CP13, RNU2-15P, LEPROT, LEPR, AC119800.1, AC097063.1, AL513493.1, RN7SL854P, PDE4B, PDE4B-AS1, RNU4-88P.
- chr8:2,873,525–5,670,140, 19 genes: AC115485.1, AC023296.1, CSMD1, AC026991.1, AC026991.2, RNA5SP251, AC027251.1, AC010941.1, AC022068.1, PAICSP4, AC019176.1, AC019176.2, SNORA70, RN7SL318P, AC007718.1, AC091193.1, RPL23AP54, AC004944.1, AC084768.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,598 genes in 51 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:185,296,388–190,478,404, 52 genes, copy number 5 (within-gene range 3–5): IVNS1ABP, AL078644.1, GS1-279B7.1, RNU7-183P, MCRIP2P2, AL133383.2, LINC01350, Y_RNA, Y_RNA, AL133383.1, HMCN1, AL133553.1, AL133553.2, PRG4, TPR, RNU6-1240P, ODR4, PDC-AS1, PDC, AL096803.3, AL096803.1, AL096803.2, AL049198.1, PTGS2, PACERR, PLA2G4A, LINC01036, AL391813.1, FDPSP1, AL357559.1, SLC4A1APP2, AL645474.1, AL136372.2, AL136372.1, RN7SKP156, AL596211.1, AL592447.1, AL929288.1, AL929288.2, RPS3AP9, AL691515.1, AL691515.2, LINC01035, CLPTM1LP1, GAPDHP75, RNA5SP73, LINC01701, AL591504.1, AL591504.2, AL359976.1, BRINP3, AL354771.1.
- chr2:38,814–29,921,586, 509 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:29,681,027–84,460,045, 884 genes, copy number 5 (broad region; genes not listed).
- chr2:94,725,674–97,589,965, 128 genes, copy number 9–20 (broad region; genes not listed).
- chr3:12,287,368–15,264,515, 63 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr3:83,924,157–91,513,775, 52 genes, copy number 5: AC092825.1, SRRM1P2, AC117464.1, LINC00971, AC117482.1, LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19, ABBA01000933.1, ABBA01000935.2.
- chr3:107,522,936–108,222,435, 7 genes, copy number 6–10 (within-gene range 6–15): BBX, LINC00636, LINC00635, AC012020.1, CD47, LINC01215, IFT57.
- chr3:110,682,286–112,081,269, 18 genes, copy number 6–10: RPSAP29, Y_RNA, NECTIN3-AS1, NECTIN3, CD96, AC092916.1, ATP6V0CP2, AC092916.2, ZBED2, NT5C3AP2, PLCXD2, PLCXD2-AS1, PHLDB2, AC117509.1, ABHD10, TAGLN3, RFKP2, TMPRSS7.
- chr3:112,140,898–112,499,472, 7 genes, copy number 8–12 (within-gene range 3–12): SLC9C1, AC128688.1, AC112487.1, AC112487.2, CD200, AC092894.1, BTLA.
- chr3:116,360,024–117,027,039, 11 genes, copy number 10–16: LSAMP-AS1, LINC00903, RN7SL582P, BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr3:166,181,313–170,860,993, 80 genes, copy number 5–26 (within-gene range 4–26) (broad region; genes not listed).
- chr4:58,939,288–59,533,898, 6 genes, copy number 5–6 (within-gene range 4–6): LINC02619, LINC02429, AC097501.1, AC108517.2, AC108517.1, Y_RNA.
- chr5:58,198–45,895,970, 710 genes, copy number 5–6 (broad region; genes not listed).
- chr6:60,281,444–68,635,161, 59 genes, copy number 5 (within-gene range 3–5): AC244258.1, GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P, AL591004.1, AL365503.1, RNA5SP208, RNU6-280P, Y_RNA, AL713998.1, AL713998.3, AL713998.4, AL713998.2, AL646090.2, AL646090.1, AL593844.1, LINC02549, AL606923.2, AL606923.1, AL391807.1.
- chr8:16,107,878–18,027,975, 33 genes, copy number 5 (within-gene range 3–5): MSR1, CCT3P1, MRPL49P2, AC011586.2, AC011586.1, RN7SL474P, FGF20, MICU3, AC079193.2, AC079193.1, ZDHHC2, CNOT7, VPS37A, MTMR7, ADAM24P, SLC7A2, AP006248.2, AP006248.4, SLC7A2-IT1, AP006248.3, PDGFRL, AP006248.1, AP006248.5, MTUS1, MIR548V, AC124069.1, RNA5SP256, AC027117.2, AC027117.1, FGL1, AC087273.1, AC087273.2, PCM1.
- chr8:49,909,789–56,218,809, 85 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr8:61,057,158–63,234,911, 31 genes, copy number 5–7 (within-gene range 3–7): CLVS1, NPM1P6, AC023866.2, AC023866.1, ASPH, KRT8P3, RN7SKP97, MIR4470, AC091173.1, LINC02842, AC025524.1, LINC02155, C1GALT1P3, NARS1P2, AC104852.1, AC023095.1, NKAIN3, AC018861.2, AC018861.1, AC090577.1, XRCC6P4, SRPK2P, AC120042.1, GGH, AC120042.2, TTPA, AC011978.1, YTHDF3-AS1, YTHDF3, AC011978.2, RN7SL135P.
- chr8:68,176,768–71,228,629, 46 genes, copy number 7 (within-gene range 2–7): AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1, LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, AC120194.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P, XKR9, AC015687.1, Y_RNA.
- chr10:933,026–6,254,644, 114 genes, copy number 5–6 (broad region; genes not listed).
- chr10:22,928,024–23,586,224, 14 genes, copy number 5: ARMC3, AL139815.1, RNA5SP304, MSRB2, YWHAZP3, AL139281.2, PTF1A, C10orf67, AL139281.1, AL606469.1, AL606469.2, OTUD1, AL512603.2, AL512603.1.
- chr11:565,660–1,892,267, 75 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr11:13,276,652–13,924,863, 19 genes, copy number 5–9 (within-gene range 3–9): ARNTL, RN7SKP151, BTBD10, AC021269.3, AC021269.1, AC021269.2, PTH, HMGN2P36, FAR1, FAR1-IT1, RPL39P26, Y_RNA, CENPUP1, AC013828.1, LINC02548, AC027779.1, LINC02545, RNA5SP331, LINC02683.
- chr11:17,349,053–18,634,791, 52 genes, copy number 10–27 (within-gene range 2–27): AC124798.2, NCR3LG1, AC124798.1, KCNJ11, ABCC8, SDHCP4, AC124798.3, USH1C, OTOG, AC124301.1, LINC02729, MYOD1, KCNC1, SERGEF, AC055860.1, TPH1, SAAL1, HIGD1AP5, SAA3P, MRGPRX3, AC090099.1, AC090099.2, MRGPRX12P, MRGPRX4, GLTPP1, MRGPRX13P, SLC25A51P4, SAA4, SAA2-SAA4, SAA2, RNA5SP333, ST13P5, SAA1, RNA5SP334, HPS5, GTF2H1, MIR3159, LDHA, AC084117.1, LDHC, AC027544.3, LDHAL6A, TSG101, YWHABP2, AC027544.2, AC027544.1, UEVLD, Metazoa_SRP, SPTY2D1OS, AC112694.1, AC112694.2, SPTY2D1.
- chr14:30,874,514–31,861,224, 25 genes, copy number 5: COCH, AL049830.3, STRN3, HIGD1AP17, MIR624, AL049830.4, AP4S1, HECTD1, RPL21P5, RNU6-541P, Y_RNA, AL136418.1, Y_RNA, HEATR5A, ATP5MC1P2, AL139353.1, AL139353.2, DTD2, AL163973.1, GPR33, NUBPL, AL163973.3, AL163973.2, RNU6-602P, RNU6-455P.
- chr14:32,934,396–35,537,054, 48 genes, copy number 5: NPAS3, AL161851.1, AL161851.2, EGLN3, EGLN3-AS1, AL356806.1, SPTSSA, RPL23AP71, EAPP, AL445363.3, AL445363.1, RNU1-27P, RNU1-28P, AL445363.2, SNX6, RPS19P3, Metazoa_SRP, RNU6-1261P, RPL23AP8, CFL2, RPL12P6, BAZ1A, RNU7-41P, AL121603.2, SRP54-AS1, AL121603.1, IGBP1P1, SRP54, FAM177A1, PPP2R3C, AL049776.1, PRORP, AL121594.1, RPL23AP70, SEPTIN7P1, MRPL57P8, DPRXP3, RPL7AP3, RPL9P3, PSMA6, AL133163.2, AL133163.1, NFKBIA, DNAJC8P1, AL133163.3, RPS3AP4, KRT18P6, INSM2.
- chr18:47,390–1,408,344, 43 genes, copy number 5 (within-gene range 4–5): TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2.
- chr18:3,284,120–4,455,307, 20 genes, copy number 6 (within-gene range 4–6): AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC, DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66.
- chr18:12,067,173–15,330,282, 117 genes, copy number 5 (broad region; genes not listed).
- chr18:22,699,481–23,672,748, 19 genes, copy number 9 (within-gene range 4–9): AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27.
- chr18:26,204,869–27,595,164, 29 genes, copy number 10: NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2.
- chr18:30,713,275–31,726,956, 24 genes, copy number 7–32: AC090506.1, AC090506.2, AC016382.1, RNU6-857P, DSC3, DSC2, DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2.
- chr19:11,666,069–19,618,693, 451 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr19:32,405,543–32,978,229, 19 genes, copy number 5 (within-gene range 3–5): DPY19L3, PDCD5, ANKRD27, SNORA68B, RPS12P31, RN7SL789P, AC008474.1, RGS9BP, AC008736.1, NUDT19, AC008736.2, TDRD12, AC008805.1, SLC7A9, AC008805.2, RN7SKP22, CEP89, RPL31P60, FAAP24.
- chr19:33,906,352–37,403,846, 194 genes, copy number 6–10 (broad region; genes not listed).
- chr19:38,526,954–40,348,527, 104 genes, copy number 6–10 (broad region; genes not listed).
- chr19:54,236,592–54,700,905, 44 genes, copy number 6: LILRA6, AC245052.6, LILRB5, RNU6-1307P, AC245052.5, LILRB2, MIR4752, AC245884.5, AC245884.12, AC245884.7, AC245884.2, LILRA5, AC245884.11, VN1R104P, AC245884.6, LILRA4, LAIR1, AC245884.4, TTYH1, AC245884.1, AC245884.9, AC245884.10, AC245884.8, LENG8-AS1, AC245884.3, LENG8, LENG9, CDC42EP5, LAIR2, AC245036.1, KIR3DX1, AC245036.2, LILRA2, AC245036.5, LILRA1, AC245036.4, LILRB1, LILRB1-AS1, LILRB4, MIR8061, VN1R105P, AC245036.3, AC243962.1, LILRP1.
- chr20:87,250–16,573,448, 302 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr20:16,748,358–17,226,146, 8 genes, copy number 6 (within-gene range 3–6): OTOR, AL121892.1, U3, RNU6-27P, AL359511.1, RNU1-131P, AL359511.2, AL359511.3.
- chr21:23,704,260–26,171,128, 37 genes, copy number 6–21 (within-gene range 1–21): AP000961.1, AP000474.2, AP000474.1, AP000477.2, AP000477.3, AP000477.1, AP000470.1, LINC01689, LINC01684, LINC01692, AP000402.1, AP000146.1, AP001342.1, AP000235.1, AP000233.2, RN7SKP236, AP000233.1, AP001341.1, RNA5SP489, RPL13AP7, AP001340.1, LINC00158, AP000221.1, MIR155HG, MIR155, AP000223.1, MRPL39, JAM2, RNGTTP1, AP000224.1, FDX1P2, ATP5PF, GABPA, LLPHP2, APP, AP001442.1, RNU6-123P.
- chr21:38,888,772–39,929,397, 35 genes, copy number 8: AP001043.1, SNORA62, RPSAP64, LINC01700, AF064858.1, AF064858.3, AF064858.2, RPL23AP12, PCBP2P1, AF129408.2, PSMG1, BRWD1, AF129408.1, TIMM9P2, BRWD1-IT1, METTL21AP1, BRWD1-AS2, BRWD1-AS1, HMGN1, Y_RNA, RNF6P1, GET1, GET1-SH3BGR, LCA5L, SH3BGR, MIR6508, MYL6P2, RPS26P4, JCADP1, B3GALT5, B3GALT5-AS1, AF064860.1, AF064860.2, IGSF5, PCP4.

Autosomal genes at a single copy (total copy number 1): 3,603. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
